MP2PRT case MP2PRT-PATHHX — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acute Lymphoblastic Leukemia; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/7b0460e9-5644-4136-9173-a4a9e3a76a70

Demographics
Sex at birth: male; Race: black or african american; Country of residence at enrollment: United States; Age at index: 5 years; Year of birth: 2004; Vital status: Alive.

Diagnoses (1)
1. Common precursor B ALL: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 5.4 years (1,985 days); Year of diagnosis: 2010; Days to last follow up: 3,720 days (10.2 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: SR-Avg Group - IS-IV arm: IC, SIM+IV-MTX, SDI, Maintenance; Days to treatment start: 0 days; Days to treatment end: 1,014 days (2.8 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Disease Progression; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 3,720 days (10.2 years); Disease response: Complete Response; Progression or recurrence: Yes; Progression or recurrence anatomic site: Overlapping lesion of brain and central nervous system; Days to recurrence: 1,014 days (2.8 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- ETV6 (FISH): Negative.
- KMT2A (FISH): Negative.
- RUNX1 (FISH): Negative.

Biospecimens (2 samples)
- Sample MP2PRT-PATHHX-NB1-A: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Sample MP2PRT-PATHHX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
